Somatic mutation profile of tumor specimen TCGA-EO-A3B1-01A (aliquot TCGA-EO-A3B1-01A-12D-A19Y-09) from TCGA case TCGA-EO-A3B1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 63.4 years (23,162 days).
Specimen TCGA-EO-A3B1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01a2697a-7538-486b-93f3-baa66859760b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3B1-10A (Blood Derived Normal), aliquot TCGA-EO-A3B1-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d654d630-1d34-4b62-a2df-aa2be4239cf0

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as rs121913275, COSV55874040, COSV55875881, COSV55956933; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 44/81 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7270C>T p.R2424W (on ENST00000614293; = p.R2394W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs759264619, COSV99687064; called by muse, mutect2, varscan2
- ACOT12 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs576654714, COSV56892736; called by muse, mutect2, varscan2
- ANKRD17 | c.1639C>A p.L547M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100428666; called by muse, mutect2, varscan2
- ARHGEF40 | c.2255G>A p.G752D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as COSV100070093; called by muse, mutect2
- ASAP2 | c.2740C>T p.L914F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV99431814; called by muse, mutect2, varscan2
- BMPER | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779064; called by mutect2, varscan2
- BSN | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99607536; called by muse, mutect2, varscan2
- CAPRIN2 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV99195434; called by muse, mutect2, varscan2
- CSMD1 | c.6533C>T p.T2178M (on ENST00000520002; = p.T2177M on NM_033225.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs762177917, COSV59326562; called by mutect2, varscan2
- DKK2 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99568269; called by muse, mutect2, varscan2
- DNAJB2 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as rs777545120, COSV100338875; called by muse, mutect2, varscan2
- FLG | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487842274, COSV100910839; called by muse, mutect2, varscan2
- GRB14 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV99813742; called by muse, mutect2, varscan2
- IGLV3-10 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs41277283; called by muse, mutect2, varscan2
- IL7R | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100285974; called by muse, mutect2, varscan2
- KCNH8 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100108827; called by muse, mutect2, varscan2
- LOX | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99140606; called by muse, mutect2, varscan2
- LTB | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV101407961; called by mutect2, varscan2
- MUC16 | c.29048T>G p.M9683R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.013); catalogued as COSV101198544; called by muse, mutect2, varscan2
- NLRP11 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs375975641; called by muse, mutect2, varscan2
- NUP205 | c.5550G>C p.E1850D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.875); catalogued as COSV99606574; called by muse, varscan2
- PPP6R3 | c.1316A>C p.E439A (on ENST00000393800 / NM_001352375.2; = p.E388A on NM_018312.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99675765; called by muse, mutect2, varscan2
- PTPRD | c.1823-1G>A p.X608_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as COSV61963009, COSV61972399; called by muse, mutect2, varscan2
- RASA1 | c.2120G>C p.R707P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57192982, COSV99169644; called by muse, mutect2, varscan2
- SALL4 | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.289); catalogued as COSV53849786; called by muse, varscan2
- SCP2D1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53857190, COSV99601912; called by muse, mutect2
- SLC38A9 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100591280; called by muse, mutect2, varscan2
- SPOP | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV100753209; called by muse, mutect2, varscan2
- TAF1 | c.2736G>T p.W912C (on ENST00000373790 / NM_138923.4; = p.W933C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111176; called by muse, mutect2, varscan2
- ZC4H2 | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100564801, COSV62004510; called by muse, mutect2, varscan2
- SH2D3C | c.1343_1355del p.E448Vfs*74 (on ENST00000314830 / NM_170600.3; = p.E291Vfs*74 on NM_005489.4) | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- GGA2 | c.1551G>A p.L517= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs748797331, COSV100564575; called by muse, mutect2, varscan2
- H2BW1 | c.132C>A p.T44= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV99474969; called by muse, mutect2, varscan2
- MED16 | c.306C>T p.D102= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs772090360, COSV99515207; called by muse, mutect2, varscan2
- NPAS4 | c.2034C>A p.G678= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs758994743, COSV100214843; called by muse, mutect2, varscan2
- PDYN | c.732G>A p.P244= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs141248791; called by muse, mutect2, varscan2
- QKI | c.684C>T p.I228= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99274438; called by muse, mutect2, varscan2
- RHOV | c.666C>A p.R222= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99592041; called by muse, mutect2
- TAAR5 | c.249G>A p.L83= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV57798915, COSV99236847; called by muse, mutect2, varscan2
- TERT | c.2796C>G p.G932= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs375675196, COSV57242017, COSV99716934; called by muse, mutect2, varscan2
- UBR4 | c.7545G>A p.L2515= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100920466; called by muse, mutect2, varscan2
